Somatic mutation profile of tumor specimen d92a2942-dba6-4fff-b0d0-0566fb (aliquot d92a2942-dba6-4fff-b0d0-0566fb_D6_1) from CPTAC case 11BR044, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 48.0 years (17,519 days).
Specimen d92a2942-dba6-4fff-b0d0-0566fb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cf21cfd-c4cc-4af0-a6f7-b36d22faf9dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen fd55a60e-fa4f-4e4e-a2b8-6273b9 (Blood Derived Normal), aliquot fd55a60e-fa4f-4e4e-a2b8-6273b9_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ef455b1-2b33-47f0-b85a-27992df7c8f8

The open-access MAF lists 53 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Intron 4, Nonsense Mutation 2, 5'UTR 1, RNA 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTPBP1 | c.3361C>T p.R1121* (on ENST00000357081 / NM_001330701.2; = p.R1081* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs773403692; called by muse, mutect2, varscan2
- AKAP8L | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 165/294 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV68474210; called by muse, mutect2, varscan2
- AQP10 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs761060478, COSV100269950; called by muse, mutect2, varscan2
- CBFB | c.165+1del p.X55_splice | Splice Site (DEL) | VAF 16/32 reads (50%) | catalogued as COSV51996680, COSV51997241, COSV51997594, COSV52002060; called by mutect2, pindel, varscan2
- CFAP77 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs773122812; called by muse, mutect2, varscan2
- CHRNA1 | c.767C>T p.P256L (on ENST00000261007 / NM_001039523.3; = p.P231L on NM_000079.4) | Missense Mutation (SNP) | VAF 222/476 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs985035699, COSV99650194; called by muse, mutect2, varscan2
- DPYS | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 24/666 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100680266; called by muse, mutect2
- FAT2 | c.12784C>T p.R4262C | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.328); catalogued as rs763266607, COSV55812550, COSV55814567; called by muse, mutect2, varscan2
- FLT3LG | c.291G>T p.L97F | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs368893926; called by muse, mutect2, varscan2
- PCDHGC5 | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs767724749; called by muse, mutect2, varscan2
- SLC8A2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746692355, COSV52639635; called by muse, mutect2, varscan2
- SNAP91 | c.2615C>A p.A872D | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV52131897; called by muse, mutect2
- TP53 | c.650T>G p.V217G | Missense Mutation (SNP) | VAF 224/445 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as COSV52675866, COSV53037841, COSV53142750, COSV53335284; called by mutect2, varscan2
- ZNF646 | c.4150C>T p.R1384W | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs769998803; called by muse, mutect2, varscan2
- ARGFX | c.369G>C p.K123N | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CCDC88B | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL18A1 | c.3886C>A p.P1296T (on ENST00000359759 / NM_130444.3; = p.P1061T on NM_030582.4) | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); called by muse, mutect2
- CYP2E1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2
- EMSY | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYA1 | c.629G>C p.S210T | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.99); called by muse, mutect2
- FBN1 | c.3810G>C p.M1270I | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLNC | c.1692G>C p.Q564H | Missense Mutation (SNP) | VAF 152/610 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN3 | c.1242C>G p.I414M | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- HNF1B | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2
- KCTD14 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.764); called by muse, mutect2
- LMTK3 | c.943_966del p.L315_F322del | In Frame Del (DEL) | VAF 26/236 reads (11%) | called by mutect2, pindel
- NBR1 | c.2308G>T p.V770F | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NR1D1 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.962); called by muse, mutect2
- OR51T1 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- PLXNA4 | c.4003C>T p.L1335F | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1L1 | c.367A>G p.N123D | Missense Mutation (SNP) | VAF 90/167 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SIPA1L1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TFEB | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- TTN | c.86375A>C p.D28792A (on ENST00000591111; = p.D21368A on NM_003319.4) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX4 | c.9658G>T p.E3220* | Nonsense Mutation (SNP) | VAF 125/666 reads (19%) | called by muse, mutect2, varscan2
- ADAM12 | c.948C>A p.I316= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs780791925, COSV64104098; called by muse, mutect2, varscan2
- ADGRB1 | c.381C>T p.C127= | Silent (SNP) | VAF 171/376 reads (45%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.1521T>C p.N507= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs745803452; called by muse, mutect2, varscan2
- CYP2F1 | c.846C>T p.H282= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs746554629; called by muse, mutect2, varscan2
- DNAH17 | c.8166T>C p.D2722= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1107C>T p.F369= | Silent (SNP) | VAF 24/480 reads (5%) | catalogued as rs137852670, CM042368, COSV54824123; called by muse, mutect2
- IRAK3 | c.570T>C p.A190= | Silent (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- IRS2 | c.2304C>T p.N768= | Silent (SNP) | VAF 34/295 reads (12%) | catalogued as rs1223957875; called by muse, mutect2, varscan2
- MMS19 | c.867T>C p.Y289= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs1287887978; called by muse, mutect2
- REXO1 | c.549G>A p.A183= | Silent (SNP) | VAF 124/232 reads (53%) | catalogued as rs762589776; called by muse, mutect2, varscan2
- SHCBP1L | c.1764A>G p.K588= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as rs1435094355; called by muse, mutect2, varscan2
- SPACA1 | c.186C>T p.Y62= | Silent (SNP) | VAF 112/247 reads (45%) | catalogued as rs765418925; called by muse, mutect2, varscan2
- EBAG9 | c.429+718C>A | Intron (SNP) | VAF 31/197 reads (16%) | catalogued as rs141523399; called by muse, mutect2, varscan2
- HERC2 | c.13273-217C>T | Intron (SNP) | VAF 58/297 reads (20%) | catalogued as rs768396990, COSV55328118; called by muse, mutect2, varscan2
- OR51F5P | n.445G>T | RNA (SNP) | VAF 106/626 reads (17%) | called by muse, mutect2, varscan2
- PDGFRA | c.2156+344C>A | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- SEMA3C | c.-30C>A | 5'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- TAMALIN | c.454+66G>T | Intron (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
